Somatic mutation profile of tumor specimen C3N-02582-01 (aliquot CPT0147880010) from CPTAC case C3N-02582, project CPTAC-3 (Bronchus and lung — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 77.3 years (28,227 days).
Specimen C3N-02582-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bafaf4aa-57a6-48f0-b709-4af34660f5f4.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02582-71 (Blood Derived Normal), aliquot CPT0147910002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3f5b4f9e-070e-40f9-b5a2-436628c45273

The open-access MAF lists 128 somatic variants for this specimen: 91 protein-altering or splice-affecting, 25 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 74, Silent 25, Intron 6, Frame Shift Del 5, 3'UTR 4, Nonsense Mutation 3, Splice Site 3, Frame Shift Ins 2, Splice Region 2, 3'Flank 1, Translation Start Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2236_2250del p.E746_A750del | In Frame Del (DEL) | VAF 409/714 reads (57%) | hotspot (GDC flag); catalogued as rs727504233, COSV51765066, COSV51849442; ClinVar: drug response; called by mutect2, pindel, varscan2
- ADH1A | c.665C>T p.A222V | Missense Mutation (SNP) | VAF 27/318 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.845); catalogued as rs781090973, COSV52924876; called by muse, mutect2
- AGTR2 | c.1049G>A p.R350Q | Missense Mutation (SNP) | VAF 13/176 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.09); catalogued as rs1468172864, COSV64156140; called by muse, mutect2
- ALS2CL | c.303G>T p.E101D | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV100015249; called by muse, mutect2
- ASPM | c.5150T>C p.I1717T | Missense Mutation (SNP) | VAF 71/281 reads (25%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs762970059; called by muse, mutect2, varscan2
- BCLAF1 | c.293A>G p.N98S | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.081); catalogued as rs1391114942; called by muse, mutect2, varscan2
- CNTNAP2 | c.361G>T p.G121W | Missense Mutation (SNP) | VAF 18/285 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62148735; called by muse, mutect2
- COL4A5 | c.4531C>T p.R1511C | Missense Mutation (SNP) | VAF 8/232 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs932623215, COSV60360534; called by muse, mutect2
- CSHL1 | c.190+4C>T | Splice Region (SNP) | VAF 22/298 reads (7%) | catalogued as rs372430128; called by muse, mutect2
- DAP3 | c.101C>T p.A34V | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0.001); catalogued as rs1019811247; called by muse, mutect2
- DCBLD2 | c.1801G>A p.E601K | Missense Mutation (SNP) | VAF 39/184 reads (21%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.833); catalogued as rs749511785, COSV54579672; called by muse, mutect2, varscan2
- DNAH1 | c.4480G>A p.V1494I | Missense Mutation (SNP) | VAF 30/217 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs369984253, COSV70232214; called by muse, mutect2, varscan2
- ECD | c.182A>G p.N61S | Missense Mutation (SNP) | VAF 20/106 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.674); catalogued as rs779617442; called by muse, mutect2
- FBN1 | c.5422+1G>T p.X1808_splice | Splice Site (SNP) | VAF 33/321 reads (10%) | catalogued as CD157730; called by muse, mutect2, varscan2
- FLT4 | c.89del p.P30Rfs*3 | Frame Shift Del (DEL) | VAF 70/230 reads (30%) | catalogued as COSV56098414; called by mutect2, varscan2
- FOCAD | c.1104A>G p.I368M | Missense Mutation (SNP) | VAF 55/263 reads (21%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as rs750076084; called by muse, mutect2, varscan2
- GJA1 | c.281C>A p.A94D | Missense Mutation (SNP) | VAF 22/544 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as COSV56996970, COSV56999820; called by muse, mutect2
- GRIK5 | c.2658C>G p.S886R | Missense Mutation (SNP) | VAF 23/175 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as COSV53482405; called by muse, mutect2, varscan2
- HEATR6 | c.467A>G p.K156R | Missense Mutation (SNP) | VAF 30/116 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.241); catalogued as rs941906178; called by muse, mutect2
- HHAT | c.892G>A p.V298M | Missense Mutation (SNP) | VAF 108/269 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs967141075, COSV99804671; called by muse, mutect2, varscan2
- HSPA9 | c.593A>G p.N198S | Missense Mutation (SNP) | VAF 73/424 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.555); catalogued as rs760210081; called by muse, mutect2, varscan2
- KDM5A | c.3709C>T p.P1237S | Missense Mutation (SNP) | VAF 81/677 reads (12%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.829); catalogued as rs1427875930; called by muse, mutect2, varscan2
- LRP12 | c.2362G>T p.V788L | Missense Mutation (SNP) | VAF 8/256 reads (3%) | SIFT tolerated, low confidence (0.67); PolyPhen benign (0); catalogued as COSV52625555; called by muse, mutect2
- LRP1B | c.1180G>A p.V394M | Missense Mutation (SNP) | VAF 22/152 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as rs1416995864; called by muse, mutect2, varscan2
- NAV3 | c.415-1G>T p.X139_splice | Splice Site (SNP) | VAF 13/264 reads (5%) | catalogued as COSV57063310; called by muse, mutect2
- NF1 | c.3344A>G p.N1115S | Missense Mutation (SNP) | VAF 22/346 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as COSV104420531; called by muse, mutect2
- NR1H3 | c.1084A>G p.I362V | Missense Mutation (SNP) | VAF 40/241 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.271); catalogued as rs368201770; called by muse, mutect2, varscan2
- ORAI1 | c.899A>G p.Y300C | Missense Mutation (SNP) | VAF 23/276 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs781854510; called by muse, mutect2
- PCDH15 | c.4449G>T p.M1483I | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.017); catalogued as COSV57316358; called by muse, mutect2
- PKD2L1 | c.1850A>T p.Q617L | Missense Mutation (SNP) | VAF 11/88 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.119); catalogued as rs1415385399; called by muse, mutect2, varscan2
- PLCD3 | c.1260G>A p.T420= | Splice Region (SNP) | VAF 14/107 reads (13%) | catalogued as rs764874906; called by muse, mutect2, varscan2
- PRDM6 | c.572A>G p.H191R | Missense Mutation (SNP) | VAF 14/243 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.08); catalogued as rs1477573403; called by muse, mutect2
- SDSL | c.544G>T p.V182L | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.19); catalogued as COSV61884641; called by muse, mutect2
- THAP5 | c.401A>T p.D134V (on ENST00000415914 / NM_001130475.3; = p.D92V on NM_182529.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.027); catalogued as COSV50812797; called by muse, mutect2, varscan2
- TSNAXIP1 | c.659G>T p.W220L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.43); PolyPhen probably damaging (0.943); catalogued as rs371204795; called by mutect2, varscan2
- TTN | c.12881C>A p.P4294H (on ENST00000591111; = p.P4248H on NM_003319.4) | Missense Mutation (SNP) | VAF 32/217 reads (15%) | catalogued as rs1468424407, COSV100626207; called by muse, mutect2, varscan2
- UBR4 | c.8473C>T p.Q2825* | Nonsense Mutation (SNP) | VAF 40/268 reads (15%) | catalogued as COSV99056544; called by muse, mutect2, varscan2
- ZFP57 | c.1211A>G p.K404R | Missense Mutation (SNP) | VAF 47/657 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.207); catalogued as COSV65306098; called by muse, mutect2
- ZNF766 | c.562G>A p.E188K | Missense Mutation (SNP) | VAF 9/80 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1337492997, COSV63009892; called by muse, mutect2
- AGO1 | c.709G>A p.D237N | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- ALB | c.1522A>T p.R508W | Missense Mutation (SNP) | VAF 34/258 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AP1M1 | c.235C>A p.L79M | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- ARHGAP18 | c.1439T>A p.M480K | Missense Mutation (SNP) | VAF 33/228 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- ASH1L | c.7085A>G p.K2362R (on ENST00000368346 / NM_001366177.2; = p.K2357R on NM_018489.3) | Missense Mutation (SNP) | VAF 12/130 reads (9%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2
- ATP6V0A1 | c.1985A>G p.Y662C | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- ATP6V1C1 | c.131dup p.V45Gfs*13 | Frame Shift Ins (INS) | VAF 79/186 reads (42%) | called by mutect2, pindel, varscan2
- BCOR | c.437G>C p.S146T | Missense Mutation (SNP) | VAF 8/158 reads (5%) | SIFT tolerated (0.29); PolyPhen benign (0.156); called by muse, mutect2
- BRD2 | c.2381A>T p.D794V | Missense Mutation (SNP) | VAF 13/217 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- CADPS2 | c.3826G>C p.V1276L | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.224); called by muse, mutect2
- CHMP1B | c.327G>T p.E109D | Missense Mutation (SNP) | VAF 15/434 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.077); called by muse, mutect2
- DDX1 | c.1436C>G p.A479G | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0); called by muse, mutect2, varscan2
- DHRS7B | c.199+2T>A p.X67_splice | Splice Site (SNP) | VAF 8/138 reads (6%) | called by muse, mutect2
- DHX29 | c.2694T>G p.Y898* | Nonsense Mutation (SNP) | VAF 7/40 reads (18%) | called by muse, mutect2, varscan2
- EEF2 | c.926_927del p.K309Rfs*77 | Frame Shift Del (DEL) | VAF 29/156 reads (19%) | called by mutect2, pindel, varscan2
- FBXL18 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 44/221 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- FLRT1 | c.74C>G p.T25S | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- GRPR | c.154C>A p.L52M | Missense Mutation (SNP) | VAF 15/145 reads (10%) | SIFT tolerated (0.1); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- LCAT | c.269T>G p.M90R | Missense Mutation (SNP) | VAF 72/229 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.697); called by muse, mutect2, varscan2
- LOX | c.1040del p.L347* | Frame Shift Del (DEL) | VAF 6/68 reads (9%) | called by mutect2, pindel
- LRRC37B | c.2194_2212del p.V732Lfs*4 | Frame Shift Del (DEL) | VAF 18/256 reads (7%) | called by mutect2, pindel
- MED23 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 37/308 reads (12%) | SIFT tolerated (0.29); PolyPhen benign (0.326); called by muse, mutect2, varscan2
- MUC16 | c.43510G>T p.E14504* | Nonsense Mutation (SNP) | VAF 11/161 reads (7%) | called by muse, mutect2
- MUC19 | c.32C>G p.S11C | Missense Mutation (SNP) | VAF 10/294 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.761); called by muse, mutect2
- NSD1 | c.698C>G p.T233S | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OGDH | c.2202G>A p.M734I | Missense Mutation (SNP) | VAF 44/197 reads (22%) | SIFT tolerated (0.06); PolyPhen benign (0.119); called by muse, mutect2, varscan2
- ORC5 | c.248T>G p.L83R | Missense Mutation (SNP) | VAF 14/182 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.091); called by muse, mutect2
- PEX2 | c.70G>C p.E24Q | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.437); called by muse, mutect2, varscan2
- PLK4 | c.1417A>G p.T473A | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2
- PLPPR3 | c.665T>C p.F222S (on ENST00000520876 / NM_001270366.2; = p.F250S on NM_024888.2) | Missense Mutation (SNP) | VAF 91/154 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- PPARA | c.755A>T p.K252M | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.838); called by muse, mutect2, varscan2
- PROKR1 | c.256G>T p.A86S | Missense Mutation (SNP) | VAF 6/116 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.062); called by muse, mutect2
- RFX6 | c.1029A>T p.L343F | Missense Mutation (SNP) | VAF 11/175 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); called by muse, mutect2
- RGS3 | c.3367A>C p.K1123Q (on ENST00000350696 / NM_001282923.2; = p.K842Q on NM_130795.4) | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.788); called by muse, mutect2
- RNF123 | c.3510A>T p.Q1170H | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2
- RNF182 | c.434G>C p.S145T | Missense Mutation (SNP) | VAF 14/174 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.007); called by muse, mutect2
- SAMD8 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 9/235 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.003); called by muse, mutect2
- SARDH | c.1382A>T p.H461L | Missense Mutation (SNP) | VAF 13/97 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- SCP2 | c.1268del p.P423Qfs*30 | Frame Shift Del (DEL) | VAF 71/287 reads (25%) | called by mutect2, pindel, varscan2
- SH3RF2 | c.482A>G p.N161S | Missense Mutation (SNP) | VAF 77/261 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SHQ1 | c.1269A>T p.E423D | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SLC66A2 | c.612C>G p.I204M | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.05); called by muse, mutect2
- SMG1 | c.7931A>G p.Y2644C | Missense Mutation (SNP) | VAF 48/346 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- TCF20 | c.1573A>T p.S525C | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2
- TMEM236 | c.689G>C p.R230P | Missense Mutation (SNP) | VAF 22/468 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.285); called by muse, mutect2
- TONSL | c.1468C>G p.L490V | Missense Mutation (SNP) | VAF 11/260 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); called by muse, mutect2
- UHRF1BP1L | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 7/159 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- UTRN | c.10222C>T p.L3408F | Missense Mutation (SNP) | VAF 65/413 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- VXN | c.576G>C p.K192N | Missense Mutation (SNP) | VAF 24/186 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF362 | c.1229C>T p.S410F | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); called by muse, mutect2
- ZNF429 | c.1685A>G p.E562G | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- ZNF655 | c.262_263insTA p.E88Vfs*10 | Frame Shift Ins (INS) | VAF 28/166 reads (17%) | called by mutect2, pindel, varscan2
- AAK1 | c.1083G>A p.E361= | Silent (SNP) | VAF 14/204 reads (7%) | called by muse, mutect2
- B4GALT5 | c.180C>T p.I60= | Silent (SNP) | VAF 17/323 reads (5%) | catalogued as rs1347088909, COSV65492464, COSV65495634; called by muse, mutect2
- BRAF | c.18T>C p.G6= | Silent (SNP) | VAF 12/202 reads (6%) | called by muse, mutect2
- CAMSAP2 | c.2205G>A p.V735= (on ENST00000236925 / NM_001297707.2; = p.V724= on NM_203459.3) | Silent (SNP) | VAF 36/374 reads (10%) | called by muse, mutect2
- DNAH5 | c.5157C>T p.F1719= | Silent (SNP) | VAF 32/283 reads (11%) | catalogued as rs749688197, COSV54247173; ClinVar: likely benign; called by muse, mutect2, varscan2
- EIF2AK2 | c.288A>G p.L96= | Silent (SNP) | VAF 15/195 reads (8%) | called by muse, mutect2
- FBXL6 | c.1587G>A p.L529= | Silent (SNP) | VAF 16/262 reads (6%) | called by muse, mutect2
- GBX1 | c.291G>A p.S97= | Silent (SNP) | VAF 24/171 reads (14%) | catalogued as rs751601645; called by muse, mutect2, varscan2
- HCAR2 | c.708G>A p.V236= | Silent (SNP) | VAF 97/426 reads (23%) | called by muse, mutect2, varscan2
- IGHV1-18 | c.330G>A p.T110= | Silent (SNP) | VAF 12/235 reads (5%) | catalogued as rs569757052; called by muse, mutect2
- KDM5A | c.3885C>T p.I1295= | Silent (SNP) | VAF 36/326 reads (11%) | called by muse, mutect2, varscan2
- LAMA1 | c.2919A>T p.P973= | Silent (SNP) | VAF 14/294 reads (5%) | called by muse, mutect2
- MAGEB5 | c.555G>A p.T185= | Silent (SNP) | VAF 76/111 reads (68%) | catalogued as rs766890533; called by muse, mutect2, varscan2
- MAP3K4 | c.600A>G p.V200= | Silent (SNP) | VAF 17/212 reads (8%) | catalogued as rs757027720; called by muse, mutect2
- MUC5AC | c.15948G>A p.P5316= | Silent (SNP) | VAF 7/175 reads (4%) | catalogued as rs1564920728; called by muse, mutect2
- NIPBL | c.5823A>G p.R1941= | Silent (SNP) | VAF 70/361 reads (19%) | catalogued as COSV99031323; called by muse, mutect2, varscan2
- NTRK3 | c.1809C>T p.F603= | Silent (SNP) | VAF 11/237 reads (5%) | called by muse, mutect2
- PHKB | c.738A>G p.L246= | Silent (SNP) | VAF 37/250 reads (15%) | called by muse, mutect2, varscan2
- SHANK2 | c.3258C>G p.V1086= | Silent (SNP) | VAF 16/309 reads (5%) | called by muse, mutect2
- SORL1 | c.6009C>T p.H2003= | Silent (SNP) | VAF 14/165 reads (8%) | catalogued as rs760941409; called by muse, mutect2
- TMED1 | c.72G>A p.A24= | Silent (SNP) | VAF 16/109 reads (15%) | catalogued as rs759176789; called by muse, mutect2, varscan2
- TONSL | c.1152C>T p.G384= | Silent (SNP) | VAF 7/155 reads (5%) | called by muse, mutect2
- TTC13 | c.753G>A p.L251= | Silent (SNP) | VAF 56/277 reads (20%) | called by muse, mutect2, varscan2
- UNKL | c.570G>A p.K190= | Silent (SNP) | VAF 13/81 reads (16%) | catalogued as rs935673902; called by muse, varscan2
- ZNF407 | c.2334A>T p.V778= | Silent (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- CLCN2 | c.1397-30C>T | Intron (SNP) | VAF 9/72 reads (13%) | catalogued as rs748343370; called by muse, mutect2, varscan2
- CPLANE1 | c.*3374A>G | 3'UTR (SNP) | VAF 53/267 reads (20%) | called by muse, mutect2, varscan2
- ESPN | chr1:6457241 C>T | 3'Flank (SNP) | VAF 20/287 reads (7%) | catalogued as rs1436366629, COSV61068016; called by muse, mutect2
- FOXP2 | c.258+36110C>A | Intron (SNP) | VAF 16/270 reads (6%) | called by muse, mutect2
- LITAF | c.*709C>T | 3'UTR (SNP) | VAF 26/433 reads (6%) | called by muse, mutect2
- MACF1 | c.15832-10174G>T | Intron (SNP) | VAF 19/190 reads (10%) | called by muse, mutect2, varscan2
- NUP155 | c.1093+21A>G | Intron (SNP) | VAF 23/186 reads (12%) | called by muse, mutect2, varscan2
- RAB17 | c.*586A>G | 3'UTR (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2
- RALGPS1 | c.910+9220C>G | Intron (SNP) | VAF 47/238 reads (20%) | catalogued as rs758344268; called by muse, mutect2, varscan2
- REV1 | c.1548-535A>T | Intron (SNP) | VAF 14/171 reads (8%) | called by muse, mutect2
- SLC35A1 | c.*5A>C | 3'UTR (SNP) | VAF 21/197 reads (11%) | called by muse, mutect2, varscan2
- ZNF658B | n.1198A>G | RNA (SNP) | VAF 49/455 reads (11%) | called by muse, mutect2, varscan2
